Somatic mutation profile of tumor specimen TCGA-XF-A8HD-01A (aliquot TCGA-XF-A8HD-01A-11D-A364-08) from TCGA case TCGA-XF-A8HD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.5 years (28,305 days).
Specimen TCGA-XF-A8HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b7e9519-f635-4cc4-8b45-e01d7f995701.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A8HD-10A (Blood Derived Normal), aliquot TCGA-XF-A8HD-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b61b790-a1ca-49b2-a245-80991f5d0d47

The open-access MAF lists 536 somatic variants for this specimen: 390 protein-altering or splice-affecting, 134 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 352, Silent 134, Nonsense Mutation 29, Intron 6, RNA 3, Splice Site 3, In Frame Del 2, Frame Shift Del 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 37/70 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC1 | c.1095C>G p.F365L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs776470140, COSV60684942; called by muse, mutect2, varscan2
- ABCF1 | c.1237G>C p.E413Q (on ENST00000326195 / NM_001025091.2; = p.E375Q on NM_001090.3) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as COSV58228875; called by muse, mutect2, varscan2
- ABI3BP | c.2524G>A p.V842M | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs753092683, COSV52534833; called by muse, mutect2, varscan2
- ACTN4 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV53145525; called by muse, mutect2, varscan2
- ADAM17 | c.1672C>G p.P558A | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.401); catalogued as COSV60398539; called by muse, mutect2, varscan2
- ADAMTS12 | c.1810C>T p.R604W | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371132100, COSV61261873; called by muse, mutect2, varscan2
- ADAMTS15 | c.2429C>G p.S810C | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV54503476; called by muse, mutect2, varscan2
- ADAMTS20 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV67130605, COSV67134713; called by muse, mutect2, varscan2
- ADGRG2 | c.2819C>G p.S940C (on ENST00000379869 / NM_001079858.3; = p.S937C on NM_005756.4) | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61338720; called by muse, mutect2, varscan2
- ADGRV1 | c.14443G>A p.E4815K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1047853698, COSV67982901; called by muse, mutect2, varscan2
- AGT | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64184449; called by muse, mutect2, varscan2
- AKAP3 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1431530339, COSV57416178, COSV57418116; called by muse, mutect2, varscan2
- AKAP8 | c.1353G>C p.L451F | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV54101731; called by muse, mutect2, varscan2
- AKNAD1 | c.1875C>G p.I625M | Missense Mutation (SNP) | VAF 39/291 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs755015083, COSV62197919; called by muse, mutect2, varscan2
- AMBRA1 | c.3016C>T p.R1006W (on ENST00000458649 / NM_001367468.1; = p.R916W on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs750314722, COSV54053056; called by muse, mutect2, varscan2
- AMOT | c.2998C>T p.Q1000* (on ENST00000371959 / NM_001113490.1; = p.Q591* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100494923; called by muse, mutect2, varscan2
- AMOTL2 | c.977G>A p.R326K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.067); catalogued as COSV51438765; called by muse, mutect2, varscan2
- ANK3 | c.10408G>C p.E3470Q | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55055795; called by muse, mutect2
- ANKRD20A4P | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 58/116 reads (50%) | catalogued as rs754343244, COSV100628483; called by muse, mutect2, varscan2
- ANO8 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.588); catalogued as rs779025602, COSV50176436; called by muse, mutect2, varscan2
- AP1B1 | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.026); catalogued as COSV58015806; called by muse, mutect2
- AP3D1 | c.2043C>G p.F681L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as COSV61427580; called by muse, mutect2, varscan2
- APBA2 | c.2033G>C p.G678A | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV68790698; called by muse, mutect2, varscan2
- AQR | c.2520C>G p.I840M | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV50033038; called by muse, mutect2, varscan2
- ARHGAP19 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV57392369, COSV57392530, COSV57393591; called by muse, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 42/76 reads (55%) | catalogued as rs758608743; called by mutect2, varscan2
- ARRDC1 | c.1011G>C p.K337N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV58374348; called by muse, mutect2
- ASXL1 | c.3187C>T p.Q1063* | Nonsense Mutation (SNP) | VAF 18/174 reads (10%) | catalogued as rs1311033207, COSV60104636; called by muse, mutect2, varscan2
- ATF7IP | c.3373C>T p.R1125* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99661146, COSV99661236; called by muse, mutect2, varscan2
- ATR | c.6625G>C p.E2209Q | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1339292607, COSV63386085; called by muse, mutect2, varscan2
- ATXN7L1 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV59492715; called by muse, mutect2, varscan2
- B4GALNT2 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55925842, COSV55929624; called by muse, mutect2, varscan2
- BBOX1 | c.302G>C p.R101T | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV54190799, COSV54192226; called by muse, mutect2, varscan2
- BDP1 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62431029; called by muse, mutect2, varscan2
- BLZF1 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV61393424, COSV61395133; called by muse, varscan2
- BLZF1 | c.1142G>C p.R381T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV61393429; called by muse, mutect2, varscan2
- BMERB1 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55507886, COSV55510008; called by muse, mutect2, varscan2
- BMP5 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV63702943; called by muse, mutect2, varscan2
- BTBD11 | c.3128C>T p.S1043L (on ENST00000280758 / NM_001018072.2; = p.S580L on NM_001017523.2) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as rs780526389, COSV55023378, COSV55031784; called by muse, mutect2, varscan2
- C8orf34 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV61378281; called by muse, mutect2, varscan2
- CACHD1 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1426139906, COSV51552437; called by muse, mutect2, varscan2
- CACNA1A | c.3958G>A p.D1320N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1568485068, COSV64196778; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.5098G>A p.E1700K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV61988911; called by muse, mutect2
- CAMTA1 | c.3490G>C p.E1164Q | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57897650; called by muse, mutect2, varscan2
- CARF | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV57547473; called by muse, mutect2, varscan2
- CARMIL1 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV61516880; called by muse, mutect2, varscan2
- CASP1 | c.721G>A p.E241K (on ENST00000436863 / NM_033292.4; = p.E220K on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as COSV62056399; called by muse, mutect2, varscan2
- CC2D2A | c.1034G>C p.G345A | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67503410; called by muse, mutect2, varscan2
- CCDC151 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV62697772; called by muse, mutect2, varscan2
- CCER1 | c.104G>C p.W35S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as COSV100726984, COSV62648449; called by muse, mutect2
- CD163L1 | c.3917G>C p.G1306A | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58015119, COSV58023097; called by muse, mutect2, varscan2
- CD2AP | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV63760541; called by muse, mutect2, varscan2
- CDH7 | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59885335; called by muse, mutect2, varscan2
- CDON | c.2696C>G p.S899C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54997484; called by muse, mutect2, varscan2
- CDR2L | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs771954882, COSV100464505; called by muse, mutect2, varscan2
- CELSR1 | c.6161G>A p.G2054D | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373457009; called by muse, mutect2, varscan2
- CEP83 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs752393422, COSV60408040; called by muse, mutect2, varscan2
- CHD9 | c.6202G>A p.E2068K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99528997; called by muse, mutect2
- CHSY1 | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV54253031; called by muse, mutect2, varscan2
- CLCN6 | c.1380C>G p.F460L | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as rs766632894, COSV56739824; called by muse, mutect2, varscan2
- CLEC4E | c.486G>C p.L162= | Splice Region (SNP) | VAF 8/57 reads (14%) | catalogued as rs758410614, COSV55225711; called by muse, mutect2, varscan2
- CLK2 | c.509G>T p.G170V (on ENST00000368361 / NM_001294339.2; = p.G169V on NM_003993.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751843; called by muse, mutect2
- CLTCL1 | c.3990G>C p.Q1330H | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV54229469; called by muse, mutect2, varscan2
- COG4 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV99850694; called by muse, mutect2
- CPAMD8 | c.1270G>C p.E424Q (on ENST00000651564; = p.E377Q on NM_015692.5) | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.359); catalogued as COSV52233733; called by muse, mutect2, varscan2
- CR2 | c.1908G>C p.L636F | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65507404; called by muse, mutect2, varscan2
- CRACD | c.3161C>T p.S1054F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV51720059; called by muse, mutect2, varscan2
- CYP2C18 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs1478268071, COSV53671954; called by muse, mutect2, varscan2
- DAPK1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776122467, COSV63785215; called by muse, mutect2, varscan2
- DCBLD2 | c.1537G>C p.D513H | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV58789178; called by muse, mutect2, varscan2
- DCDC1 | c.449C>G p.S150C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV60841132, COSV60847542; called by muse, mutect2, varscan2
- DCST2 | c.1550G>A p.G517D | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55051521; called by muse, mutect2, varscan2
- DDX4 | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | catalogued as COSV100737459, COSV61755078; called by muse, mutect2, varscan2
- DDX58 | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV59379517, COSV59382726; called by muse, mutect2, varscan2
- DNAH7 | c.7351G>C p.D2451H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs984004369, COSV56753131, COSV56762425; called by muse, mutect2, varscan2
- DOK5 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs780293083, COSV52819629; called by muse, mutect2
- DUSP1 | c.488C>A p.S163Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV53319743, COSV53319977; called by muse, mutect2, varscan2
- EIF2AK2 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV51796098; called by muse, mutect2, varscan2
- ELMO2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV51682652; called by muse, mutect2
- ENC1 | c.503C>G p.S168C | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.951); catalogued as rs373404351; called by muse, mutect2, varscan2
- EP300 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.298); catalogued as rs1392142896, COSV54331757; called by muse, mutect2
- EPB41L4B | c.2688G>C p.L896F | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65802932; called by muse, mutect2, varscan2
- ERBB4 | c.2058G>C p.L686F | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53527449; called by muse, mutect2
- ERI2 | c.677C>A p.A226D | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55501164; called by muse, mutect2, varscan2
- ERICH3 | c.1897C>G p.H633D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV58605472; called by muse, mutect2
- ERICH3 | c.706C>G p.P236A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100443914; called by muse, mutect2
- EXPH5 | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.637); catalogued as COSV56201588; called by muse, mutect2, varscan2
- EXPH5 | c.1844C>A p.S615Y | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56201600; called by muse, mutect2, varscan2
- EXPH5 | c.1595C>T p.S532L | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV56201609, COSV56209453; called by muse, mutect2, varscan2
- FAM210A | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV59184130; called by muse, mutect2
- FAM81B | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51982520, COSV51985554; called by muse, mutect2, varscan2
- FANCD2 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as COSV55036892; called by muse, mutect2, varscan2
- FAT4 | c.5468C>A p.S1823* | Nonsense Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV100628060, COSV58676301; called by muse, mutect2, varscan2
- FAT4 | c.5573C>G p.S1858C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58682327; called by muse, mutect2, varscan2
- FBLN7 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV55616062; called by muse, mutect2, varscan2
- FBN2 | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV52509635; called by muse, mutect2, varscan2
- FBXO8 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV67031414; called by muse, mutect2, varscan2
- FCRLA | c.696C>G p.F232L (on ENST00000367959; = p.F209L on NM_032738.4) | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52685647; called by muse, mutect2, varscan2
- FGD1 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100910978; called by muse, mutect2, varscan2
- FHOD3 | c.3343G>T p.E1115* (on ENST00000359247 / NM_001281739.3; = p.E1132* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 20/292 reads (7%) | catalogued as COSV99940770; called by muse, mutect2
- FLCN | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53259076; called by muse, mutect2, varscan2
- FLG | c.9448G>C p.D3150H | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV64241026; called by muse, mutect2, varscan2
- FLNB | c.4627G>A p.D1543N | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55878149; called by muse, mutect2, varscan2
- FMNL2 | c.2161C>T p.H721Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as rs1465398996, COSV56490237; called by muse, mutect2
- FRRS1 | c.917G>T p.R306I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.171); catalogued as COSV54921770; called by muse, mutect2, varscan2
- GAB2 | c.1499G>A p.R500Q (on ENST00000361507 / NM_080491.3; = p.R462Q on NM_012296.3) | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs370982595, COSV60867265; called by muse, mutect2, varscan2
- GABBR2 | c.351C>G p.F117L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as COSV52301839, COSV99409331; called by muse, mutect2, varscan2
- GABRB1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104402153, COSV54979472; called by muse, mutect2, varscan2
- GBP7 | c.1878T>G p.C626W | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV54009425; called by muse, mutect2, varscan2
- GIMAP6 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV61033294; called by muse, mutect2, varscan2
- GIPR | c.336G>A p.W112* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99624509; called by muse, mutect2, varscan2
- GJB5 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as COSV58356048; called by muse, mutect2
- GLI3 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV67887920; called by muse, mutect2, varscan2
- GNB1L | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61548409; called by muse, mutect2, varscan2
- GNL3 | c.669G>C p.K223N | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV56477402; called by muse, mutect2, varscan2
- GPD2 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV60092388; called by muse, mutect2, varscan2
- GRIN2A | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58030605; called by muse, mutect2, varscan2
- GRIN2B | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370809599, COSV99078317; called by muse, mutect2
- GUCY1A2 | c.1782G>C p.L594F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56485151; called by muse, mutect2, varscan2
- H1-5 | c.16C>G p.P6A | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV58899875; called by muse, mutect2, varscan2
- HAUS3 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV54722570; called by muse, mutect2, varscan2
- HEATR6 | c.2180C>A p.S727Y | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51745190; called by muse, mutect2, varscan2
- HERC1 | c.14071C>T p.R4691* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as rs951302383, COSV71246789; called by muse, mutect2
- HIVEP1 | c.5641A>G p.T1881A | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV65100849; called by muse, mutect2, varscan2
- HMCN1 | c.1066C>G p.P356A | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54896671, COSV54901742; called by muse, mutect2, varscan2
- HNRNPU | c.2054C>G p.S685* (on ENST00000283179; = p.S747* on NM_004501.3) | Nonsense Mutation (SNP) | VAF 27/206 reads (13%) | catalogued as COSV99310139; called by muse, mutect2, varscan2
- HOXC11 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1470973157, COSV54533064; called by muse, mutect2, varscan2
- HSPA8 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV57083777; called by muse, mutect2, varscan2
- HYDIN | c.14869G>C p.E4957Q | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs950907355, COSV66638726; called by muse, mutect2, varscan2
- IGF2BP2 | c.1098G>C p.L366F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60482985, COSV60485474; called by muse, mutect2, varscan2
- IGLC2 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs371508809; called by muse, mutect2, varscan2
- INSYN2A | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.173); catalogued as rs781714055, COSV54738181; called by muse, mutect2, varscan2
- IPO8 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | catalogued as COSV99805051; called by muse, mutect2, varscan2
- IQCG | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as COSV54561879; called by muse, mutect2, varscan2
- IQGAP1 | c.2386C>G p.Q796E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.103); catalogued as COSV51584923; called by muse, mutect2, varscan2
- IRAK3 | c.533A>T p.E178V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.773); catalogued as COSV54161283; called by muse, mutect2, varscan2
- ITGB2 | c.1800G>C p.E600D (on ENST00000302347; = p.E576D on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100185739; called by muse, mutect2
- ITGB8 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs267601448, COSV56004613; called by muse, mutect2, varscan2
- ITPRID2 | c.3568C>G p.P1190A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV57471294; called by muse, mutect2
- JRK | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs782306597, COSV70630037; called by muse, mutect2, varscan2
- KCNB2 | c.1288C>A p.Q430K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV73049955, COSV73051765; called by muse, mutect2, varscan2
- KCNJ3 | c.100C>G p.Q34E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54535382, COSV99715582; called by muse, mutect2
- KCNJ6 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0.078); catalogued as rs777214818, COSV55713458; called by muse, mutect2, varscan2
- KCNS3 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as rs1385877160, COSV58406509; called by muse, mutect2, varscan2
- KCTD21 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.444); catalogued as COSV60741039; called by muse, mutect2, varscan2
- KIAA0753 | c.1598G>T p.R533I | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63817291; called by muse, mutect2, varscan2
- KIF13A | c.2535G>C p.E845D | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV52449300; called by muse, mutect2, varscan2
- KMT2A | c.7311C>G p.F2437L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV63285269; called by muse, mutect2, varscan2
- KMT2A | c.9787C>G p.P3263A | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63285281; called by muse, mutect2, varscan2
- KMT2A | c.10736C>G p.S3579* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | catalogued as COSV100628466, COSV104417863; called by muse, mutect2, varscan2
- KMT2D | c.3205G>T p.E1069* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV56411515, COSV56495976; called by muse, mutect2
- KMT2D | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99979571; called by muse, mutect2, varscan2
- KNDC1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58835985; called by muse, mutect2, varscan2
- KRT37 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.503); catalogued as rs1170728942, COSV56657870; called by mutect2, varscan2
- KRT77 | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV59239568; called by muse, mutect2, varscan2
- LARP7 | c.1222C>G p.Q408E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1454058535, COSV60520779; called by muse, mutect2, varscan2
- LEPR | c.3290A>C p.K1097T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100848379, COSV62747328; called by muse, mutect2, varscan2
- LGALSL | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99482420; called by muse, mutect2, varscan2
- LIX1 | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV57206825; called by muse, mutect2, varscan2
- LOXL2 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750311862, COSV66691321; called by muse, mutect2, varscan2
- LRFN5 | c.384G>C p.L128F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV53247978, COSV53254215; called by muse, mutect2, varscan2
- LRP10 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as COSV62078174; called by muse, mutect2, varscan2
- LRP12 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as COSV52628193; called by muse, mutect2, varscan2
- LRRC43 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60289687; called by muse, mutect2
- LRRC43 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60289698; called by muse, mutect2
- LRRK2 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as rs1341703796, COSV100109726; called by muse, mutect2, varscan2
- MACC1 | c.1947C>G p.I649M | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV60542325; called by mutect2, varscan2
- MACF1 | c.19907G>C p.R6636T (on ENST00000372915; = p.R4681T on NM_012090.5) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV57119009; called by muse, mutect2, varscan2
- MAN2A1 | c.3215G>C p.R1072T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV54851060; called by muse, mutect2, varscan2
- MAP3K1 | c.1933G>C p.D645H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68123306; called by muse, mutect2, varscan2
- MAP3K19 | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV59638439; called by muse, mutect2, varscan2
- MAP3K4 | c.2221C>T p.R741W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62332957; called by muse, mutect2, varscan2
- MAP4K3 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV55712497; called by muse, mutect2, varscan2
- MCM3AP | c.5716C>G p.Q1906E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV52439182; called by muse, mutect2, varscan2
- MCM5 | c.361C>T p.L121F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as rs1331471368, COSV53346116; called by muse, mutect2
- MED1 | c.3332C>T p.S1111L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV56124451; called by muse, mutect2, varscan2
- MED13 | c.2086G>A p.D696N | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67263271; called by muse, mutect2, varscan2
- MEI1 | c.1557G>C p.Q519H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55902643, COSV55902731; called by muse, mutect2, varscan2
- METTL25 | c.531+1G>A p.X177_splice | Splice Site (SNP) | VAF 28/95 reads (29%) | catalogued as rs771477466, COSV50258790; called by muse, mutect2, varscan2
- MLLT3 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV63497204; called by muse, mutect2, varscan2
- MMAA | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs757207009, COSV55579937; called by muse, mutect2, varscan2
- MMP9 | c.435C>A p.F145L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV63434029; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV64055387; called by muse, mutect2, varscan2
- MPP5 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV55529421; called by muse, mutect2, varscan2
- MPP6 | c.1571T>G p.I524R | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV56037797; called by muse, mutect2, varscan2
- MTUS1 | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.103); catalogued as COSV100030001, COSV50555708; called by muse, mutect2, varscan2
- MUC17 | c.6740C>T p.T2247I | Missense Mutation (SNP) | VAF 85/563 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV60287101; called by muse, mutect2, varscan2
- MYBPC3 | c.903G>C p.K301N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1311354477, CD0911259, COSV99920148; called by muse, mutect2, varscan2
- MYO5A | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV62559632; called by muse, mutect2, varscan2
- MYO9A | c.3764G>C p.R1255T | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as COSV61850279; called by muse, mutect2, varscan2
- MYO9B | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV68278426, COSV68278755; called by muse, mutect2, varscan2
- MYT1 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV60505038; called by muse, mutect2, varscan2
- N4BP2L1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.831); catalogued as COSV58412811; called by muse, mutect2, varscan2
- N6AMT1 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100374943; called by muse, mutect2, varscan2
- NBPF3 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV59058730; called by muse, mutect2, varscan2
- NCAPD2 | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as COSV59699102; called by muse, mutect2, varscan2
- NDUFAB1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV104375400, COSV50287228; called by muse, mutect2, varscan2
- NELFCD | c.1498G>C p.E500Q (on ENST00000602795; = p.E482Q on NM_198976.4) | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV53883135; called by muse, varscan2
- NEUROD2 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56910958; called by muse, mutect2, varscan2
- NHLRC2 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV65174769, COSV65174806; called by muse, mutect2, varscan2
- NLRC5 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as COSV52654322; called by muse, mutect2, varscan2
- NLRP13 | c.2024C>A p.S675* | Nonsense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100738135, COSV61621910; called by muse, mutect2, varscan2
- NLRP6 | c.1500G>C p.Q500H | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.319); catalogued as rs750162668, COSV56459382; called by muse, mutect2, varscan2
- NLRP8 | c.739G>C p.E247Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52586541; called by muse, mutect2, varscan2
- NOA1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.683); catalogued as COSV51736746; called by muse, mutect2, varscan2
- NOTCH3 | c.4625C>T p.S1542L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV54647816; called by muse, mutect2, varscan2
- NR2F1 | c.417A>C p.Q139H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59068194; called by muse, mutect2, varscan2
- NR5A2 | c.1114G>A p.D372N (on ENST00000367362 / NM_205860.3; = p.D326N on NM_003822.5) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.15); catalogued as rs1403852059, COSV52649486, COSV99030626; called by muse, mutect2, varscan2
- NRIP1 | c.1708C>G p.Q570E | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as COSV59656986; called by muse, mutect2, varscan2
- NSMAF | c.805T>A p.Y269N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV50686318; called by muse, mutect2, varscan2
- ODF2 | c.1743G>C p.E581D (on ENST00000434106 / NM_153433.2; = p.E557D on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV63546789; called by muse, mutect2, varscan2
- OGFRL1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs777810665, COSV64971638, COSV64972534; called by muse, mutect2, varscan2
- OR4A16 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV59042872, COSV59045268; called by muse, mutect2, varscan2
- OR4K5 | c.893T>C p.V298A | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV60003344; called by muse, mutect2, varscan2
- P4HB | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100515799; called by muse, mutect2, varscan2
- PAAF1 | c.529G>C p.G177R | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV60155371; called by muse, mutect2, varscan2
- PALD1 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV54972867; called by muse, mutect2, varscan2
- PALD1 | c.930C>A p.F310L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210598613, COSV54972881; called by muse, mutect2, varscan2
- PALLD | c.2251G>C p.E751Q (on ENST00000505667 / NM_001166108.2; = p.E734Q on NM_016081.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54979557; called by muse, mutect2, varscan2
- PAPSS1 | c.1280G>C p.G427A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1161576681, COSV54488852; called by muse, mutect2, varscan2
- PARVB | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as COSV58686391; called by muse, mutect2, varscan2
- PCDH15 | c.4261G>A p.A1421T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV57300778; called by muse, mutect2, varscan2
- PCDHGA3 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.235); catalogued as rs1487000938, COSV99534898; called by muse, mutect2, varscan2
- PDE1B | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV54492347; called by muse, mutect2, varscan2
- PDP2 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 24/155 reads (15%) | catalogued as COSV100305869; called by muse, mutect2, varscan2
- PFAS | c.1391G>C p.G464A | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58980000; called by muse, mutect2, varscan2
- PHF20L1 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs769446293, COSV55191837; called by muse, mutect2, varscan2
- PHRF1 | c.1825G>A p.G609R (on ENST00000264555 / NM_001286581.2; = p.G608R on NM_020901.4) | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52755060; called by muse, mutect2, varscan2
- PITPNM1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs933400579, COSV56873366; called by muse, mutect2, varscan2
- PIWIL1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55346274; called by muse, mutect2, varscan2
- PJA2 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV100754551, COSV63272571; called by muse, mutect2, varscan2
- PLCB1 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62048601; called by muse, mutect2
- PLEC | c.7901C>T p.S2634F (on ENST00000322810 / NM_201380.4; = p.S2524F on NM_000445.5) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs1554689367, COSV59631349; called by muse, mutect2, varscan2
- PLRG1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV57423390; called by muse, mutect2, varscan2
- PLXNC1 | c.2038G>A p.V680M | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs375403794; called by muse, mutect2, varscan2
- POLA2 | c.1585G>T p.A529S | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.287); catalogued as rs546255396, COSV55482842, COSV55482976; called by muse, mutect2, varscan2
- POLE | c.4795G>T p.E1599* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as COSV100265945; called by muse, mutect2, varscan2
- POLH | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763654639, COSV64779393; called by muse, mutect2, varscan2
- PPA2 | c.703C>T p.L235F (on ENST00000341695 / NM_176869.3; = p.L206F on NM_006903.4) | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs765143005, COSV58995184; called by muse, mutect2, varscan2
- PPFIA1 | c.1191G>C p.Q397H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54133972; called by muse, mutect2, varscan2
- PPOX | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV57088432; called by muse, varscan2
- PPOX | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | catalogued as rs770279631, COSV99237288; called by muse, varscan2
- PRDM8 | c.143A>G p.H48R | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV60203415; called by muse, mutect2, varscan2
- PRKCD | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV57848343; called by muse, mutect2, varscan2
- PRPF3 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61394661; called by muse, mutect2, varscan2
- PRPF6 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs761921786, COSV53869808; called by muse, mutect2, varscan2
- PRSS27 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV57013308; called by muse, mutect2, varscan2
- PRTG | c.2318T>C p.L773P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV66837808; called by muse, mutect2, varscan2
- PRUNE2 | c.3181G>A p.D1061N | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV65040985; called by muse, mutect2, varscan2
- PSMB7 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV52330365; called by muse, mutect2
- PSMB9 | c.549G>C p.M183I | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as COSV66399502; called by muse, mutect2, varscan2
- PSMD3 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs142613700; called by muse, mutect2, varscan2
- PTPRZ1 | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV66435595; called by muse, mutect2, varscan2
- RALGAPB | c.2021C>T p.T674M | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs375925256; called by muse, mutect2, varscan2
- RASA2 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV53939271; called by muse, mutect2, varscan2
- RBBP6 | c.4284G>C p.E1428D | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV60504742; called by muse, mutect2, varscan2
- RBL1 | c.3051C>G p.I1017M | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60329698; called by muse, mutect2, varscan2
- RBM19 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765861178, COSV55691215; called by muse, mutect2, varscan2
- RBM39 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV53615056; called by muse, varscan2
- RBM48 | c.402del p.K134Nfs*9 | Frame Shift Del (DEL) | VAF 20/111 reads (18%) | catalogued as rs754768719; called by mutect2, pindel, varscan2
- RGS18 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV66507977; called by muse, mutect2, varscan2
- RNF145 | c.1255C>G p.L419V (on ENST00000424310 / NM_001199383.2; = p.L447V on NM_144726.2) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV50865993; called by muse, mutect2, varscan2
- RNF170 | c.33G>C p.L11F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.028); catalogued as COSV53566664; called by mutect2, varscan2
- RNF213 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV60622927; called by muse, mutect2
- ROBO1 | c.4234G>C p.E1412Q | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV71393922; called by muse, mutect2, varscan2
- RP1L1 | c.5782G>A p.E1928K | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV66754469; called by muse, mutect2, varscan2
- RPRD2 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV64819792; called by muse, mutect2, varscan2
- RPS6KA3 | c.1258G>A p.D420N | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); catalogued as COSV65387663; called by muse, mutect2, varscan2
- RPTN | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 55/397 reads (14%) | catalogued as COSV100285403, COSV60166671; called by muse, mutect2, varscan2
- RSF1 | c.3449G>A p.R1150Q | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1328866981, COSV57839245; called by muse, mutect2, varscan2
- RUFY1 | c.1395G>T p.Q465H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60159731; called by mutect2, varscan2
- RUFY3 | c.1669G>C p.E557Q | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV66814842; called by muse, mutect2, varscan2
- RYR2 | c.9217G>T p.E3073* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1197392727, COSV100769234, COSV100773354; called by muse, mutect2, varscan2
- RYR3 | c.4798G>A p.G1600S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759747259, COSV66786064; called by muse, mutect2, varscan2
- S100A14 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.153); catalogued as COSV59884600, COSV59885291; called by muse, mutect2, varscan2
- SAFB | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.791); catalogued as COSV52651089, COSV99385415; called by muse, mutect2, varscan2
- SCTR | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1189518791, COSV50027812; called by muse, mutect2, varscan2
- SDAD1 | c.1436C>G p.A479G | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62402671; called by muse, mutect2, varscan2
- SEPTIN7 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 29/255 reads (11%) | catalogued as COSV100621737; called by muse, mutect2, varscan2
- SERGEF | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV56383042; called by muse, mutect2, varscan2
- SESN3 | c.1335G>C p.E445D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs766389916, COSV53584656; called by muse, mutect2, varscan2
- SHPRH | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV51608576; called by muse, mutect2, varscan2
- SHROOM4 | c.1583C>A p.S528Y | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV56788460; called by muse, mutect2, varscan2
- SIN3A | c.3268G>T p.D1090Y | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64582691; called by muse, mutect2, varscan2
- SLAIN2 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99971580; called by muse, mutect2, varscan2
- SLC12A4 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.42); catalogued as rs769702101, COSV57928844; called by muse, mutect2, varscan2
- SLC16A10 | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.792); catalogued as COSV64354191; called by muse, mutect2, varscan2
- SLC25A13 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs771117913, COSV55703524, COSV55706553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC27A4 | c.950C>A p.S317Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs532636378, COSV55959798; called by muse, mutect2, varscan2
- SLC34A3 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV63186969; called by muse, mutect2, varscan2
- SLC35E4 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55898978; called by muse, mutect2, varscan2
- SLC36A3 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.223); catalogued as COSV100077989, COSV58856720; called by muse, mutect2, varscan2
- SLC39A12 | c.1101C>A p.Y367* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV66196765, COSV66197171, COSV66200399; called by muse, mutect2, varscan2
- SLC6A5 | c.1303A>C p.I435L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54225962; called by muse, mutect2, varscan2
- SLC9C2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV62945488; called by muse, mutect2, varscan2
- SMARCC2 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs985132459, COSV57217812; called by muse, mutect2, varscan2
- SMC1A | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447236; called by muse, mutect2, varscan2
- SMCHD1 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.129); catalogued as COSV99861225; called by muse, mutect2
- SMTNL2 | c.718C>T p.P240S (on ENST00000389313 / NM_001114974.2; = p.P96S on NM_198501.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58807853; called by muse, mutect2, varscan2
- SPG7 | c.1264G>C p.E422Q (on ENST00000268704; = p.E429Q on NM_003119.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.343); catalogued as COSV51950186; called by muse, mutect2, varscan2
- SPHKAP | c.3367G>C p.E1123Q | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60876885, COSV60897107; called by muse, mutect2, varscan2
- SPTAN1 | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV63986836; called by muse, mutect2, varscan2
- SPTBN4 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV58948282; called by muse, mutect2, varscan2
- SRPRA | c.1801A>G p.I601V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as rs2230546; called by muse, mutect2, varscan2
- STIM1 | c.1615C>G p.Q539E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); catalogued as COSV100330922, COSV100331132, COSV56154202; called by muse, varscan2
- SWI5 | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV60791973; called by muse, varscan2
- SYNE2 | c.3838G>C p.E1280Q | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59949026; called by muse, mutect2, varscan2
- SYNGAP1 | c.3652G>C p.E1218Q | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV53380724; called by muse, mutect2, varscan2
- TBKBP1 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64653578; called by muse, mutect2, varscan2
- TCHH | c.5240G>C p.R1747T | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); catalogued as COSV64274478; called by muse, varscan2
- TCHH | c.5166G>C p.E1722D | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64274484; called by muse, varscan2
- TCOF1 | c.3703C>G p.L1235V (on ENST00000377797 / NM_001135243.1; = p.L1158V on NM_000356.4) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.262); catalogued as COSV60348063; called by muse, mutect2, varscan2
- TCP11L1 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57515068; called by muse, mutect2, varscan2
- THAP12 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52610403; called by muse, mutect2, varscan2
- THAP12 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV52610415; called by muse, mutect2, varscan2
- TIAM1 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV54548652; called by muse, mutect2, varscan2
- TIGD7 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.404); catalogued as COSV51915906; called by muse, mutect2, varscan2
- TIGD7 | c.609G>C p.K203N | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.078); catalogued as COSV51915912; called by muse, mutect2, varscan2
- TIMP2 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53160655; called by muse, mutect2, varscan2
- TINAGL1 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 72/124 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as COSV54698953; called by muse, mutect2, varscan2
- TKT | c.1230C>G p.I410M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV56245204; called by muse, mutect2
- TLE4 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54631206; called by muse, mutect2, varscan2
- TMEFF1 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV58490766, COSV58492916; called by muse, mutect2, varscan2
- TNPO1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV100473236; called by muse, mutect2
- TOR1AIP1 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54869366; called by muse, mutect2, varscan2
- TOR3A | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV61680061; called by muse, mutect2, varscan2
- TRAPPC10 | c.2660C>T p.S887L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52377064; called by muse, mutect2, varscan2
- TRIM33 | c.3064G>C p.D1022H | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV61821241, COSV61822270; called by muse, mutect2, varscan2
- TRIM75P | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs1244266491, COSV72295830; called by muse, mutect2, varscan2
- TSPYL6 | c.795G>A p.M265I | Missense Mutation (SNP) | VAF 86/151 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV57814299; called by muse, mutect2, varscan2
- TTC12 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100133023; called by muse, mutect2, varscan2
- UBA6 | c.2146C>G p.L716V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs1160930388, COSV100451639; called by muse, mutect2
- UBE2U | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV64280862; called by muse, mutect2, varscan2
- UBE2Z | c.402G>C p.L134F | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62875696; called by muse, mutect2
- UBE3B | c.737C>G p.S246* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV55095819, COSV99783877; called by muse, mutect2, varscan2
- UGT3A2 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.961); catalogued as COSV56930252; called by muse, mutect2, varscan2
- UNC13C | c.3388G>C p.E1130Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.336); catalogued as rs1299940028, COSV52867743; called by muse, mutect2, varscan2
- UNC13D | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776737156, CM112830, COSV52884054; called by muse, mutect2, varscan2
- USP28 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50161145; called by muse, mutect2, varscan2
- USPL1 | c.1808C>T p.S603F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV54999784; called by muse, mutect2, varscan2
- UTP23 | c.689G>C p.R230T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100561210, COSV59124147; called by muse, mutect2, varscan2
- VCAN | c.6773C>T p.S2258L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54103959; called by muse, mutect2, varscan2
- VCPIP1 | c.3625G>A p.D1209N | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as COSV60047037; called by muse, mutect2, varscan2
- VILL | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.362); catalogued as COSV52184340; called by muse, mutect2, varscan2
- VPS16 | c.2122C>T p.H708Y | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs1448824164, COSV66794617; called by muse, mutect2, varscan2
- VWA7 | c.1440C>G p.I480M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1417723235, COSV100991794; called by muse, mutect2
- VWA7 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373092700, COSV63304540; called by muse, mutect2, varscan2
- WASHC2C | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); catalogued as rs1235237048, COSV60491169; called by muse, mutect2, varscan2
- WDR17 | c.2150T>C p.L717P | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV54572784; called by muse, mutect2, varscan2
- WDR93 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51531983; called by muse, mutect2, varscan2
- WDR93 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.731); catalogued as COSV51530597; called by muse, mutect2, varscan2
- WNK2 | c.3536C>A p.S1179Y | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99941753; called by muse, mutect2
- YIPF1 | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs138000802; called by muse, mutect2
- YY1AP1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV55120929; called by muse, mutect2, varscan2
- ZBED2 | c.573G>A p.M191I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs1401056102, COSV104368363, COSV51914547; called by muse, mutect2, varscan2
- ZC2HC1A | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373208347; called by muse, mutect2, varscan2
- ZCCHC2 | c.3395C>T p.S1132L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54037471; called by muse, mutect2, varscan2
- ZDHHC8 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs200092859, COSV57710019; called by muse, mutect2, varscan2
- ZEB2 | c.1395G>C p.Q465H | Missense Mutation (SNP) | VAF 71/124 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV100357370, COSV57956139; called by muse, mutect2, varscan2
- ZFHX4 | c.7181C>A p.S2394* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99260773; called by muse, mutect2, varscan2
- ZFP30 | c.1027C>T p.L343F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.54); PolyPhen probably damaging (1); catalogued as rs767021926, COSV63622578; called by muse, mutect2, varscan2
- ZFPL1 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV51869315; called by muse, mutect2, varscan2
- ZNF106 | c.3427C>T p.Q1143* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99782409; called by muse, mutect2, varscan2
- ZNF215 | c.1446G>T p.M482I | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV53492828, COSV53494618; called by muse, mutect2, varscan2
- ZNF232 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.986); catalogued as COSV51503225; called by muse, mutect2, varscan2
- ZNF280A | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 99/171 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV57480400, COSV57481216; called by muse, mutect2, varscan2
- ZNF292 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1408166723, COSV60538872; called by muse, mutect2, varscan2
- ZNF318 | c.5789C>G p.S1930C | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.821); catalogued as rs1247575205, COSV58932199; called by muse, mutect2, varscan2
- ZNF324 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs764888667, COSV52180577, COSV52181288; called by muse, mutect2, varscan2
- ZNF326 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.08); catalogued as COSV61035127; called by muse, mutect2
- ZNF329 | c.929C>A p.T310K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63772278; called by muse, mutect2, varscan2
- ZNF404 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.392); catalogued as COSV100182457; called by muse, mutect2
- ZNF461 | c.1296G>C p.Q432H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV64453580; called by muse, mutect2, varscan2
- ZNF534 | c.988C>G p.L330V (on ENST00000332323 / NM_001143939.3; = p.L317V on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as COSV56516617; called by muse, mutect2, varscan2
- ZNF558 | c.906G>T p.R302S | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.177); catalogued as COSV56863042, COSV56863458; called by muse, mutect2
- ZNF607 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs753698330, COSV67696203; called by muse, mutect2, varscan2
- ZNF626 | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV74129414; called by muse, mutect2, varscan2
- ZNF695 | c.611G>C p.R204T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.37); catalogued as COSV60585732; called by muse, mutect2, varscan2
- ZNF714 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV52510963, COSV99395439; called by muse, mutect2, varscan2
- ZZZ3 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66232530; called by muse, mutect2, varscan2
- CFAP65 | c.5389_5391del p.E1797del | In Frame Del (DEL) | VAF 14/98 reads (14%) | called by pindel, varscan2
- CLVS1 | c.631-3_661del p.X211_splice | Splice Site (DEL) | VAF 30/187 reads (16%) | called by mutect2, pindel
- ENPP7 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FRG2 | c.525G>T p.L175F | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KTN1 | c.187_195del p.K63_K65del | In Frame Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- RHOXF2 | c.80-1G>C p.X27_splice | Splice Site (SNP) | VAF 14/20 reads (70%) | called by mutect2, varscan2
- TLN2 | c.1220_1225delinsTACT p.Q407Lfs*10 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by pindel, varscan2*
- ABCA7 | c.1560C>T p.G520= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as rs1406365823, COSV54027097; called by muse, mutect2, varscan2
- AC004922.1 | c.1584C>T p.F528= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs140888847; called by muse, mutect2
- ACADM | c.795T>A p.G265= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as COSV57714349; called by muse, mutect2, varscan2
- ADCY9 | c.882C>T p.I294= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV53574644; called by muse, mutect2, varscan2
- ADIPOR1 | c.594G>A p.E198= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV61851409; called by muse, mutect2, varscan2
- AGGF1 | c.786G>A p.P262= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs1398716532, COSV57227948; called by muse, mutect2, varscan2
- AGO2 | c.1596C>G p.V532= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV55046991; called by muse, mutect2, varscan2
- AHNAK | c.14148C>T p.I4716= | Silent (SNP) | VAF 67/388 reads (17%) | catalogued as COSV57211959; called by muse, mutect2, varscan2
- AMBP | c.195G>A p.V65= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV54323313; called by muse, mutect2, varscan2
- ANKRD10 | c.333G>A p.L111= | Silent (SNP) | VAF 37/146 reads (25%) | catalogued as COSV57443582; called by muse, mutect2, varscan2
- ARAF | c.1593C>A p.L531= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV51692350; called by muse, mutect2, varscan2
- ASPM | c.9399T>C p.A3133= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV54128962; called by muse, mutect2, varscan2
- ASTN2 | c.1284G>A p.L428= (on ENST00000313400 / NM_001365069.1; = p.L377= on NM_014010.5) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs138130190, COSV57773893; called by muse, mutect2, varscan2
- ATP1A4 | c.2211C>T p.G737= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV63626349; called by muse, mutect2, varscan2
- ATXN1 | c.1449G>A p.V483= | Silent (SNP) | VAF 47/165 reads (28%) | catalogued as COSV55214984; called by muse, mutect2, varscan2
- C12orf42 | c.660C>T p.I220= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs763470684, COSV59382075; called by muse, mutect2, varscan2
- CA2 | c.180C>G p.L60= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV53406575; called by muse, mutect2, varscan2
- CACNG5 | c.84C>T p.V28= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV50055632; called by muse, mutect2, varscan2
- CAPN3 | c.768C>T p.I256= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs748032310, COSV58821438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC191 | c.555G>A p.Q185= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV55671809; called by muse, mutect2, varscan2
- CCDC47 | c.693G>C p.L231= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV56722866; called by muse, mutect2, varscan2
- CDC42BPB | c.1740G>C p.L580= | Silent (SNP) | VAF 45/118 reads (38%) | catalogued as COSV63474779; called by muse, mutect2, varscan2
- CDH8 | c.27C>T p.L9= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV54863771; called by muse, mutect2, varscan2
- CEACAM18 | c.915G>A p.L305= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV67282731; called by muse, mutect2, varscan2
- CELSR3 | c.993G>A p.Q331= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV50853611; called by muse, mutect2, varscan2
- CFAP100 | c.343C>T p.L115= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61502943; called by muse, mutect2, varscan2
- CILP | c.2790C>T p.N930= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs368147396; called by muse, mutect2, varscan2
- CNGB1 | c.2580C>T p.F860= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV51900275; called by muse, mutect2, varscan2
- COPG1 | c.1728C>G p.L576= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV59113849; called by muse, mutect2, varscan2
- CPXM1 | c.1111C>T p.L371= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV66045258; called by muse, mutect2, varscan2
- CRB2 | c.1797C>T p.V599= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs1305258773, COSV63502895; called by muse, mutect2, varscan2
- CRH | c.423C>A p.L141= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs774790655, COSV52541889, COSV52542039; called by muse, mutect2, varscan2
- CRHBP | c.801T>C p.F267= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV57188353; called by muse, mutect2, varscan2
- CTTN | c.1620C>G p.L540= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100097443; called by muse, mutect2
- CUX2 | c.2400C>T p.Y800= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs765690123, COSV55625429; called by muse, mutect2, varscan2
- DCP1A | c.492C>T p.A164= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53688446; called by muse, mutect2, varscan2
- DDX11 | c.2121C>T p.F707= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs1336893009, COSV52499068, COSV52503514; called by muse, mutect2, varscan2
- DHX33 | c.1800G>A p.R600= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV56578812; called by muse, mutect2
- DNAH17 | c.2644C>T p.L882= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV67753416; called by muse, mutect2, varscan2
- DNAH5 | c.13212C>G p.L4404= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV54221032; called by muse, mutect2, varscan2
- DOCK5 | c.4887C>G p.L1629= | Silent (SNP) | VAF 29/187 reads (16%) | catalogued as COSV52400458; called by muse, mutect2, varscan2
- DSTYK | c.2115G>A p.P705= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs200118459, COSV65686309; called by mutect2, varscan2
- ECEL1 | c.387C>T p.F129= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as rs775731269, COSV58811989; called by muse, varscan2
- EMC6 | c.138C>T p.L46= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs370563455; called by muse, mutect2, varscan2
- EPHA8 | c.492C>G p.L164= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV51267218; called by muse, mutect2, varscan2
- EPN3 | c.1575C>T p.P525= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV52139534; called by muse, mutect2, varscan2
- F2RL2 | c.1036C>T p.L346= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV56970547; called by muse, mutect2, varscan2
- FARP1 | c.807G>A p.L269= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV60336110; called by muse, mutect2, varscan2
- FBXW10 | c.1611C>T p.I537= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100111316, COSV100111437; called by muse, mutect2, varscan2
- FLACC1 | c.483C>G p.L161= | Silent (SNP) | VAF 30/47 reads (64%) | catalogued as rs1237015396, COSV53783511, COSV99630010; called by muse, mutect2, varscan2
- FOXF2 | c.474C>T p.F158= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as COSV52525667; called by muse, mutect2, varscan2
- G6PD | c.1491G>A p.K497= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as COSV100854991; called by muse, mutect2, varscan2
- GBP4 | c.561C>T p.F187= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as rs1557475548, COSV63254017, COSV63255073; called by muse, mutect2, varscan2
- GPNMB | c.345C>G p.V115= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV51698138; called by muse, mutect2, varscan2
- HCK | c.1580G>A p.*527= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV52940698; called by muse, mutect2, varscan2
- HEPH | c.81C>A p.V27= (on ENST00000343002; = p.V81= on NM_138737.5) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs201273147, COSV100294570; called by muse, varscan2
- HNRNPL | c.1359C>G p.V453= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs765184825, COSV55492413, COSV55492565; called by muse, mutect2, varscan2
- HPD | c.261G>A p.V87= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as COSV56641826; called by muse, mutect2, varscan2
- HPX | c.690C>T p.P230= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV56419192, COSV56419450; called by muse, mutect2, varscan2
- IFNL3 | c.313C>T p.L105= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV69829953; called by muse, mutect2, varscan2
- KALRN | c.1821G>A p.T607= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs373414085; called by muse, mutect2, varscan2
- KMT2A | c.10287C>T p.L3429= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV63285286; called by muse, mutect2, varscan2
- KRT19 | c.162C>T p.S54= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100843676; called by muse, mutect2, varscan2
- L3MBTL1 | c.1299G>T p.L433= (on ENST00000418998 / NM_001377303.1; = p.L343= on NM_015478.7) | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as COSV64228353; called by muse, mutect2, varscan2
- LAMC1 | c.4542C>G p.L1514= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV51139482; called by muse, mutect2, varscan2
- LNX1 | c.1611C>T p.V537= (on ENST00000263925 / NM_001126328.3; = p.V441= on NM_032622.2) | Silent (SNP) | VAF 51/142 reads (36%) | catalogued as COSV55784955; called by muse, mutect2, varscan2
- LOXL1 | c.1158G>A p.Q386= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV56094194; called by muse, mutect2, varscan2
- LPAR6 | c.948C>T p.F316= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV57303361, COSV57307458, COSV99926504; called by muse, mutect2, varscan2
- LSR | c.1785G>C p.V595= (on ENST00000361790; = p.V576= on NM_015925.6) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1488774967, COSV55886913; called by muse, mutect2
- MADD | c.3387G>A p.V1129= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV60623647; called by muse, mutect2, varscan2
- MAP3K6 | c.2358C>G p.L786= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV62888380; called by muse, mutect2, varscan2
- MCL1 | c.402C>G p.L134= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV100329709, COSV57190273; called by muse, mutect2, varscan2
- MMP13 | c.717C>T p.L239= | Silent (SNP) | VAF 67/172 reads (39%) | catalogued as COSV52823838, COSV52824923; called by muse, mutect2, varscan2
- MTFR1 | c.597G>T p.L199= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV50951619; called by muse, mutect2, varscan2
- MTOR | c.3987G>C p.L1329= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV63868732; called by muse, mutect2, varscan2
- MYBPC3 | c.2211G>A p.T737= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs113265977, COSV57026577; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH9 | c.5199G>A p.Q1733= | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs766468427, COSV53385521; called by muse, varscan2
- MYOCD | c.1635G>A p.L545= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV58502753; called by muse, mutect2, varscan2
- NBEAL2 | c.4434G>A p.Q1478= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99435448; called by muse, mutect2
- NEFL | c.774C>G p.L258= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1412176798, COSV55336874; called by muse, mutect2, varscan2
- NFE2L2 | c.1017C>T p.F339= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as COSV101229385, COSV67960987; called by muse, mutect2, varscan2
- NLRP4 | c.1986G>A p.L662= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV56712659; called by muse, mutect2, varscan2
- OPRL1 | c.1107C>T p.P369= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs376089460, COSV61091599; called by muse, mutect2, varscan2
- OR52L1 | c.486C>A p.I162= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV59986837, COSV59989188; called by muse, mutect2, varscan2
- OR8I2 | c.639C>T p.I213= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV56167509; called by muse, mutect2, varscan2
- PCDH7 | c.2901C>T p.V967= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV62338448; called by muse, mutect2, varscan2
- PDGFRL | c.621C>A p.L207= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV52411962; called by muse, mutect2, varscan2
- PEG3 | c.150G>A p.R50= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs765526274, COSV55631899; called by muse, mutect2, varscan2
- PIGQ | c.1809C>T p.H603= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs780075779, COSV50312234; called by muse, mutect2, varscan2
- PLEKHG6 | c.159C>T p.L53= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV50599896, COSV50603063; called by muse, mutect2, varscan2
- PLOD3 | c.2097G>A p.V699= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV56182626; called by muse, mutect2, varscan2
- PLXNA4 | c.4506G>C p.L1502= | Silent (SNP) | VAF 26/151 reads (17%) | catalogued as COSV58121510; called by muse, mutect2, varscan2
- PPP2R1B | c.75C>T p.I25= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as rs1555053139, COSV59535386; called by muse, mutect2
- PPP6R3 | c.2136G>A p.P712= (on ENST00000393800 / NM_001352375.2; = p.P632= on NM_018312.5) | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs1308392348, COSV99675819; called by muse, mutect2
- PRDM10 | c.1833C>T p.I611= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as COSV58800855; called by muse, mutect2, varscan2
- PTPRZ1 | c.6849G>C p.V2283= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV66435602, COSV66441725; called by muse, mutect2, varscan2
- RASAL1 | c.1395C>T p.I465= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV55655600; called by muse, mutect2, varscan2
- RBBP8NL | c.1698G>C p.L566= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV53349007; called by muse, mutect2, varscan2
- RBFA | c.519G>A p.L173= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV100080277, COSV51533633; called by muse, mutect2, varscan2
- RELN | c.864G>A p.K288= | Silent (SNP) | VAF 100/219 reads (46%) | catalogued as rs1057523268, COSV104414860, COSV58999362; ClinVar: likely benign; called by muse, mutect2, varscan2
- RFC1 | c.2844G>A p.L948= (on ENST00000381897 / NM_001363496.2; = p.L947= on NM_002913.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV62899395; called by muse, mutect2, varscan2
- RGS6 | c.672G>A p.K224= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV59575057; called by muse, mutect2, varscan2
- RGS9 | c.202C>T p.L68= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as COSV52225000; called by muse, mutect2, varscan2
- SBNO2 | c.1827G>A p.Q609= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV62320312; called by muse, mutect2, varscan2
- SIPA1L2 | c.4194C>T p.I1398= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs755604550, COSV53386004, COSV53389484; called by muse, mutect2, varscan2
- SIVA1 | c.237G>A p.P79= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs769691789, COSV57331514; called by muse, mutect2, varscan2
- SLC12A5 | c.972C>A p.V324= (on ENST00000454036 / NM_001134771.2; = p.V301= on NM_020708.5) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV54792728; called by muse, mutect2, varscan2
- SLC15A4 | c.693C>T p.V231= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV57161272; called by muse, mutect2
- SLC38A10 | c.3249C>T p.N1083= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs768107383, COSV66101137; called by muse, mutect2, varscan2
- SLC6A11 | c.1359G>A p.V453= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV54392968; called by muse, mutect2, varscan2
- SMG1 | c.5238C>G p.L1746= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV67173371; called by muse, mutect2
- SNX29 | c.153C>G p.A51= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV73829724; called by muse, mutect2, varscan2
- SOS1 | c.3105A>G p.L1035= | Silent (SNP) | VAF 72/118 reads (61%) | catalogued as rs749104275, COSV67675005; called by muse, mutect2, varscan2
- SPTB | c.1836C>T p.I612= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV67631473; called by muse, mutect2, varscan2
- SSTR1 | c.321C>A p.L107= | Silent (SNP) | VAF 26/158 reads (16%) | catalogued as COSV57455764, COSV57457049; called by muse, mutect2, varscan2
- STAG3 | c.3033C>G p.L1011= | Silent (SNP) | VAF 32/226 reads (14%) | catalogued as COSV57929997; called by muse, mutect2, varscan2
- SWI5 | c.168C>G p.L56= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as COSV60791980; called by muse, varscan2
- TAP1 | c.909C>T p.F303= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV62753906; called by muse, mutect2, varscan2
- TEX15 | c.5445A>G p.G1815= (on ENST00000256246; = p.G2198= on NM_001350162.2) | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV56345535; called by muse, mutect2
- TFRC | c.1281G>A p.L427= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV64054621; called by muse, mutect2, varscan2
- TMEM94 | c.2637C>T p.I879= | Silent (SNP) | VAF 31/192 reads (16%) | catalogued as rs1223120249, COSV58595195; called by muse, mutect2, varscan2
- TMUB2 | c.189C>T p.S63= (on ENST00000538716 / NM_001353177.2; = p.S43= on NM_024107.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV60228716; called by muse, mutect2, varscan2
- TPH2 | c.1236C>T p.I412= | Silent (SNP) | VAF 18/105 reads (17%) | catalogued as rs958594402, COSV61591774; called by muse, mutect2, varscan2
- TRIM46 | c.1728G>C p.L576= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV100104842, COSV58113449; called by muse, mutect2, varscan2
- TRPM2 | c.1764C>T p.L588= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs762486032, COSV100308193, COSV100308513; called by muse, mutect2
- TRPM7 | c.417A>G p.V139= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV57915895; called by muse, mutect2, varscan2
- UBC | c.1035G>A p.Q345= | Silent (SNP) | VAF 48/320 reads (15%) | catalogued as COSV60059343; called by muse, varscan2
- UQCRH | c.258C>T p.L86= | Silent (SNP) | VAF 64/142 reads (45%) | catalogued as COSV61176358; called by muse, mutect2, varscan2
- VPS13D | c.5806C>A p.R1936= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as COSV50635420; called by muse, mutect2, varscan2
- XKR7 | c.939C>T p.R313= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as rs754406842, COSV73813134; called by muse, mutect2, varscan2
- ZDHHC12 | c.460C>T p.L154= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV52576401; called by muse, mutect2, varscan2
- ZNF460 | c.1053C>G p.L351= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs969106299, COSV64415632; called by muse, mutect2, varscan2
- ZNF644 | c.2142C>T p.S714= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as rs758219229, COSV61346963; called by muse, mutect2, varscan2
- ZWINT | c.639C>T p.L213= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs1428866712, COSV59185260; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701035 G>T | 3'Flank (SNP) | VAF 19/104 reads (18%) | called by muse, mutect2, varscan2
- CEP295 | c.5850+108G>A | Intron (SNP) | VAF 20/90 reads (22%) | catalogued as COSV100292189; called by muse, mutect2, varscan2
- CPLANE1 | c.*5194G>A | 3'UTR (SNP) | VAF 18/84 reads (21%) | catalogued as COSV57058719; called by muse, mutect2, varscan2
- FBLN1 | c.186-2419G>C | Intron (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99410378; called by muse, mutect2
- FMO3 | c.133-2040G>C | Intron (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100882419, COSV63006748; called by muse, mutect2, varscan2
- GULP1 | c.-172+4457G>C | Intron (SNP) | VAF 5/29 reads (17%) | catalogued as rs1022262507, COSV100770458; called by muse, mutect2
- MIR920 | n.74C>A | RNA (SNP) | VAF 13/74 reads (18%) | catalogued as rs552344258, COSV69039726; called by muse, mutect2
- PDP1 | c.-109G>A | 5'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as rs775128777, COSV99892182; called by muse, mutect2, varscan2
- RPL23A | c.26-132C>G | Intron (SNP) | VAF 25/104 reads (24%) | catalogued as COSV52644268; called by muse, mutect2, varscan2
- SNORD114-14 | n.44G>A | RNA (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- TMEM183B | n.838C>T | RNA (SNP) | VAF 44/281 reads (16%) | called by muse, mutect2, varscan2
- TTN | c.10360+2508G>A | Intron (SNP) | VAF 21/84 reads (25%) | catalogued as rs866726793, COSV60018777; called by muse, mutect2, varscan2
